Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A4MC, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A4MC-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Thyroid, total thyroidectomy

ICD-0.3
carcinoma, papillary thyroid 8260/3
Site: thyroid, NOS low
C73.9 10/2/12

Tumor histologic type: papillary

Tumor size: 2.8 cm

Tumor growth pattern: circumscribed

Tumor focality: unifocal, right superior pole

Extent of invasion:

Capsular Invasion: not encapsulated

Lymphovascular: not identified

Blood vascular: not identified

Extra thyroidal extension: present (A1, A3)

Surgical margins:

- Not involved, focally to 1 mm of the anterior and posterior margins of the right superior pole

Status of thyroid gland away from tumor: nodular hyperplasia

Lymph nodes: submitted separately

AJCC Stage: pT3 pN1b

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph node, right neck level 3, excision

- Metastatic papillary thyroid carcinoma (1/1), 7mm diameter, without extracapsular extension

Clinical History:

-year-old female with malignant thyroid neoplasm.

Gross Description:

Specimen A is labeled "total right thyroid, stitch superior".

Specimen fixation: Formalin

[page 2 of 3]
Type of specimen: Total thyroidectomy

Size and weight of specimen: 24.4 grams, composed of a 4.8 x 2.2 x 2.3 cm right lobe, 4.2 x 1.7 x 1.7 cm left lobe, central contiguous isthmus and a 2.2 x 0.8 x 0.5 cm pyramidal lobe.

Orientation: Anterior/blue, posterior/black, and isthmus/yellow. The specimen is sectioned from superior towards inferior .

Tumor location: Right superior pole.

Focality: Unifocal

Dominant tumor: Yes

Tumor description: Solid white/tan with a gritty cut surface and irregular borders.

Tumor size: 2.8 x 1.9 x 1.7 cm

Confinement/non-confinement:: Appears confined to the thyroid although it expands the right superior pole anteriorly with focally adherent cauterized fibrous tissue.

Distance of tumor to surgical margins: Focally abuts the anterior blue inked margin and the posterior black inked margin as well as the superior pole of the right thyroid.

Appearance of thyroid gland away from tumor: Dark red/brown and unremarkable with the exception of a 0.6 cm gelatinous cyst in the left upper pole, lined by smooth glistening borders. The isthmus and pyramidal lobe are grossly unremarkable

Parathyroids: Not identified

Tissue submitted for special investigations: Tumor is given to tissue procurement.

Lymph nodes: Submitted separately.

Digital photograph taken: No

Block Summary:

Inking: Anterior/blue, posterior/black, isthmus/yellow

A1 - Perpendicular sections of right superior pole

A2 - Next section, right superior pole

A3 - Next section

[page 3 of 3]
A4-A5 - Inferior edge of tumor

A6 - Representative sections from pyramidal lobe

A7-A8 - Representative sections from left lobe

Specimen B is labeled "right neck lymph node level 3" and is a 1.2 x 0.9 x 0.4 cm firm gray/tan lymph node candidate with a small amount of attached fat and is serially sectioned to reveal a solid tan/gray cut surface, B1,

	Yes	No
Original		
Discrepancy		X
History Discrepancy		X
Previous Malignancy History		X
Discrepancy Primary Malignancy		X
Reviewed:	9/27/12	

KMI

10/2/12

Source: NCI Genomic Data Commons file c481fcef-bd48-4410-80ae-d06d28a41c62 (TCGA-DE-A4MC.FAD65DE3-2C89-4A88-AB39-6B9B9BC0954C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).